Somatic mutation profile of tumor specimen MMRF_1893_1_BM_CD138pos (aliquot MMRF_1893_1_BM_CD138pos_T1_KBS5U_L05559) from MMRF case MMRF_1893, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 38.5 years (14,050 days).
Specimen MMRF_1893_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6df97cbe-5aa4-4260-8f3e-e431fc142a6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1893_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1893_1_PB_Whole_C3_KBS5U_L05580; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79d6c729-7e25-4fde-bef7-e4e4d8cd58d5

The open-access MAF lists 52 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, 3'UTR 13, Silent 7, RNA 3, Intron 3, 5'Flank 2, Nonsense Mutation 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.42769C>T p.R14257* (on ENST00000591111; = p.R6833* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as rs775186117, CM1514720, COSV59899605, COSV60000160; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD17 | c.3247C>T p.H1083Y | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV58217842; called by muse, mutect2
- ARVCF | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs761530180; called by muse, mutect2, varscan2
- GATAD1 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1261746364, COSV55319491; called by muse, mutect2
- IFT74 | c.1435A>G p.T479A | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs539904016; called by muse, mutect2, varscan2
- IGHJ6 | c.36A>C p.K12N | Missense Mutation (SNP) | VAF 26/70 reads (37%) | PolyPhen benign (0); catalogued as rs377600355; called by muse, varscan2
- IGHV2-70 | c.152G>C p.S51T | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs372640551; called by muse, varscan2
- IGHV2-70 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs373039668; called by muse, varscan2
- IGLC2 | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.537); catalogued as rs373362171; called by muse, mutect2, varscan2
- LAMC2 | c.1972C>A p.Q658K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.026); catalogued as rs887305342; called by muse, mutect2, varscan2
- PFKP | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1009839767; called by muse, mutect2, varscan2
- SUGCT | c.1285G>A p.A429T (on ENST00000335693 / NM_001193313.2; = p.A455T on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs753739815, COSV59311982; called by muse, mutect2, varscan2
- CNTN5 | c.839T>A p.V280D | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DACH2 | c.646A>C p.T216P | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ELK4 | c.465G>C p.L155F | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPS15L1 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLV3-25 | c.250A>C p.S84R | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.02); called by muse, varscan2
- SP100 | c.1135G>T p.V379L | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- TP63 | c.1925T>C p.V642A | Missense Mutation (SNP) | VAF 75/309 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.43310C>T p.P14437L (on ENST00000591111; = p.P7013L on NM_003319.4) | Missense Mutation (SNP) | VAF 10/213 reads (5%) | PolyPhen benign (0.242); called by muse, mutect2
- UGT8 | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- USP38 | c.885A>T p.K295N | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CDC42BPB | c.2829A>G p.K943= | Silent (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- HAUS8 | c.483A>G p.V161= | Silent (SNP) | VAF 25/119 reads (21%) | called by muse, mutect2, varscan2
- IGLV3-25 | c.189G>C p.V63= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as rs192338803; called by muse, varscan2
- OR8J1 | c.198G>A p.L66= | Silent (SNP) | VAF 81/492 reads (16%) | catalogued as rs997205556; called by muse, mutect2, varscan2
- PCDHA3 | c.1719C>T p.I573= | Silent (SNP) | VAF 55/111 reads (50%) | catalogued as rs1554122439, COSV63543091, COSV63545984; called by muse, mutect2, varscan2
- PLEKHA4 | c.522C>T p.P174= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs571371427, COSV54364188; called by muse, mutect2
- SERPINH1 | c.441G>A p.V147= | Silent (SNP) | VAF 71/356 reads (20%) | called by muse, mutect2, varscan2
- AC079154.1 | n.1083T>C | RNA (SNP) | VAF 89/331 reads (27%) | called by muse, mutect2, varscan2
- ANKRD13A | c.*1713T>A | 3'UTR (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- CMKLR1 | c.*3228C>T | 3'UTR (SNP) | VAF 50/168 reads (30%) | catalogued as rs548716486; called by muse, mutect2, varscan2
- CORO7 | c.*55T>C | 3'UTR (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- DDB1 | c.*58C>G | 3'UTR (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- ELAVL2 | chr9:23691361 A>G | 3'Flank (SNP) | VAF 45/114 reads (39%) | called by muse, mutect2, varscan2
- FAM199X | c.*1668A>T | 3'UTR (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- GALNT13 | c.*309T>C | 3'UTR (SNP) | VAF 33/119 reads (28%) | called by muse, mutect2, varscan2
- IGHV3-21 | c.-20_-7del | 5'UTR (DEL) | VAF 31/151 reads (21%) | called by pindel, varscan2
- KLHL4 | c.*1408T>G | 3'UTR (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- LINC02207 | n.1846A>G | RNA (SNP) | VAF 29/74 reads (39%) | called by muse, mutect2, varscan2
- MIR5195 | n.36A>C | RNA (SNP) | VAF 32/88 reads (36%) | called by muse, varscan2
- MIR5195 | chr14:106851258 C>G | 5'Flank (SNP) | VAF 42/208 reads (20%) | catalogued as rs147455610; called by muse, varscan2
- NCOA2 | c.*3445T>C | 3'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- NCOA2 | c.*1538C>T | 3'UTR (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- NCOA2 | c.*683A>G | 3'UTR (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- NIN | c.265+32C>A | Intron (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- NRG1 | c.503-6024C>A | Intron (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- RAD51C | c.*30T>G | 3'UTR (SNP) | VAF 108/381 reads (28%) | catalogued as rs1326226531; called by muse, mutect2, varscan2
- SIRPA | c.*727C>T | 3'UTR (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- SOX11 | c.*58G>A | 3'UTR (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- THY1 | c.37+90C>T | Intron (SNP) | VAF 37/149 reads (25%) | called by muse, mutect2, varscan2
- ZBTB10 | chr8:80485589 ins T | 5'Flank (INS) | VAF 12/52 reads (23%) | called by mutect2, pindel
